TCGA case TCGA-3A-A9I9 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/396ff766-a383-4f42-bce3-f2f32b7f1151

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 634 days (1.7 years); Cause of death: Cancer Related; Cause of death source: Death Certificate.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 67.7 years (24,731 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 23; Tumor largest dimension diameter: 2.5 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 73 days; Days to treatment end: 265 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 97 days; Days to treatment end: 336 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 97 days; Days to treatment end: 134 days; Treatment outcome: Stable Disease; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 294 days; Days to treatment end: 336 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone + Megestrol Acetate; Days to treatment start: 518 days (1.4 years); Days to treatment end: 620 days (1.7 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Oxaliplatin; Days to treatment start: 518 days (1.4 years); Days to treatment end: 620 days (1.7 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Liver. Age at diagnosis: 69.1 years (25,244 days); Days to diagnosis: 513 days (1.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 513 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 513 days (1.4 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 634 days (1.7 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 75; Tobacco smoking quit year: 2007.
- Alcohol history: Yes; Alcohol intensity: Drinker; Alcohol drinks per day: 2; Alcohol days per week: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3A-A9I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-3A-A9I9-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-3A-A9I9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3A-A9I9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tissue Biopsy; Lymph nodes examined: Yes; Tumor status: With tumor; Cause of death: Pancreatic Cancer; Tobacco smoking history indicator: 4; Alcohol exposure intensity: Weekly Drinker; Alcohol consumption frequency: 1; Diabetes diagnosis indicator: No; History chronic pancreatitis: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Megace.
- Drug treatment 4: Pharmaceutical therapy drug name: 5 FU.
- Drug treatment 6: Pharmaceutical therapy drug name: 5 FU; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 634 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 634 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 513 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3A-A9I9-01A-11D-A38F-01): tumor purity 0.32, ploidy 1.86, whole-genome doublings 0.
